Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A948, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-A948-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Left testis

Left testis:

Mixed germ cell tumor

- immature teratoma (60%)
- endodermal sinus tumor (20%)
- embryonal carcinoma (20%)

Present infiltration of tunica albuginea without perforation

Margins uninvolved by neoplasia

Spermatic cord margin uninvolved by neoplasia.

Epididymis uninvolved by neoplasia.

200-0-3
Mixed germ cell tumor 9085/3
Site @ Testis NOS 062.9
JW 3/3/14

h.p.a.a. Discrepancy		

Source: NCI Genomic Data Commons file 1c51834c-8c71-4c51-ba8a-51dabd06486a (TCGA-YU-A948-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).